Somatic mutation profile of tumor specimen MP2PRT-PAUBPJ-TMP1-A (aliquot MP2PRT-PAUBPJ-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUBPJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (732 days).
Specimen MP2PRT-PAUBPJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b80eda6-df12-4015-b92d-cc054cab75ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBPJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBPJ-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/672ed72c-1b9f-4f2a-a0d9-91874dc275d8

The open-access MAF lists 35 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENOX2 | c.445G>A p.E149K (on ENST00000338144 / NM_001382520.1; = p.E120K on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 241/632 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.71); catalogued as rs747944133, COSV100584325, COSV57656535; called by muse, mutect2, varscan2
- MCL1 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 27/800 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV57190680; called by muse, mutect2
- MKI67 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 61/427 reads (14%) | catalogued as rs142132992; called by muse, mutect2, varscan2
- OR10A4 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV65841784, COSV65842586; called by muse, mutect2
- PCDHB14 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 18/684 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV53386204; called by muse, mutect2
- PCYT1B | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 115/392 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1174221637; called by muse, mutect2, varscan2
- RNASEH2C | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 25/474 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs769127379; called by muse, mutect2
- SLC47A1 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs141945405; called by muse, mutect2, varscan2
- SYNE1 | c.13948C>T p.R4650* (on ENST00000367255 / NM_182961.4; = p.R4579* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 38/357 reads (11%) | catalogued as rs866163858, COSV55096185; called by muse, mutect2, varscan2
- ARHGAP4 | c.86G>C p.S29T | Missense Mutation (SNP) | VAF 145/565 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CASKIN1 | c.1509C>G p.I503M | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CELF4 | c.657+1G>T p.X219_splice | Splice Site (SNP) | VAF 54/470 reads (11%) | called by mutect2, varscan2
- CREBBP | c.5042_5043insCGGAGAGCCATCA p.L1681Ffs*58 | Frame Shift Ins (INS) | VAF 137/677 reads (20%) | called by mutect2, pindel, varscan2
- ETV6 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 175/276 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSTCD | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 109/385 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HEPACAM | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 354/961 reads (37%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NTN1 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 24/746 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- OR5T1 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); called by muse, mutect2
- PEG10 | c.305T>C p.I102T (on ENST00000482108 / NM_001040152.2; = p.I136T on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2
- POLR1A | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SND1 | c.767T>C p.L256P | Missense Mutation (SNP) | VAF 22/615 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- SUPT3H | c.926G>A p.G309D (on ENST00000371460 / NM_181356.3; = p.G298D on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.564); called by muse, mutect2
- TEX29 | c.104G>T p.R35M | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOM1L1 | c.1024del p.S342Qfs*3 | Frame Shift Del (DEL) | VAF 70/336 reads (21%) | called by mutect2, pindel, varscan2
- WDR62 | c.2404C>G p.L802V | Missense Mutation (SNP) | VAF 17/496 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2
- ZFP14 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 16/518 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.392); called by muse, mutect2
- ZNF658 | c.2683T>A p.S895T | Missense Mutation (SNP) | VAF 140/397 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CUL7 | c.4437G>T p.L1479= | Silent (SNP) | VAF 13/449 reads (3%) | catalogued as COSV54823801; called by muse, mutect2
- MFHAS1 | c.1092C>G p.L364= | Silent (SNP) | VAF 17/441 reads (4%) | called by muse, mutect2
- OR6M1 | c.102A>G p.T34= | Silent (SNP) | VAF 126/357 reads (35%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1590C>T p.G530= | Silent (SNP) | VAF 121/915 reads (13%) | catalogued as COSV50692466; called by muse, mutect2, varscan2
- PCK1 | c.651G>A p.T217= | Silent (SNP) | VAF 140/396 reads (35%) | catalogued as rs777897405, COSV60130408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTF1 | c.603G>A p.E201= | Silent (SNP) | VAF 93/224 reads (42%) | catalogued as COSV67477636; called by muse, mutect2, varscan2
- BRSK2 | c.91+21162G>A | Intron (SNP) | VAF 30/899 reads (3%) | called by muse, mutect2
- SULT1A4 | chr16:29466764 C>T | 3'Flank (SNP) | VAF 17/479 reads (4%) | called by muse, mutect2
